Surgical pathology report (de-identified scan), TCGA case TCGA-23-1110, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Cedars Sinai, specimen TCGA-23-1110-01A (Primary Tumor).

[page 1 of 5]
PATIENT: [REDACTED] PATH #: [REDACTED]
Hospital No.: [REDACTED] A/S: [REDACTED]
Date of Birth: [REDACTED] Rec: [REDACTED]
Soc. Sec. No.: [REDACTED] Col: [REDACTED]
Location: [REDACTED]
Pathologist: [REDACTED]
Assistant: [REDACTED]
Attending MD: [REDACTED]
Ordering MD: [REDACTED]
Copies To: [REDACTED]

=====

DIAGNOSIS:

- 1,2. RIGHT TUBE AND OVARY AND LEFT TUBE AND OVARY, BILATERAL SALPINGO-OOPHORECTOMY:
- Primary ovarian poorly differentiated papillary serous carcinoma with transitional cell component (20%), FIGO grade III
- Tumor dimension:
- Right ovary: 14.5 x 10.5 x 4.5 cm
- Left ovary: 11.0 x 7.0 x 3.5 cm
- The tumor involves bilateral ovarian surfaces
- Lymphovascular space invasion present in right ovary
- Recognizable residual right ovarian parenchyma is noted showing few simple cysts, surface adhesions and corpora albicans
- Scanty recognizable ovary is noted on the left side showing no significant histopathologic changes
- Extension into paraovarian soft tissue noted in the left ovary
- Left fallopian tube shows surface fibrin with admixed detached malignant cells
- Right fallopian tube shows no evidence of involvement with tumor
3. BLADDER BIOPSY:
- Metastatic papillary serous carcinoma
- Reactive mesothelial hyperplasia with psammomatous calcifications and fibrovascular and mature adipose tissue
4. PELVIC TUMOR, EXCISION:
- Metastatic papillary serous carcinoma
- Associated necrosis, psammomatous calcifications, reactive mesothelial hyperplasia
5. OMENTUM #1, PARTIAL OMENECTOMY:
- Metastatic papillary serous carcinoma with necrosis and psammomatous calcifications
- Mesothelial-lined fibroadipose tissue with foci of mesothelial hyperplasia, chronic inflammation and vascular congestion

(continued on next page)□

6. OMENTUM #2, PARTIAL OMENECTOMY:
- Metastatic papillary serous carcinoma
- Mesothelial-lined lobulated fibroadipose tissue with fibroadhesions, reactive mesothelial hyperplasia and chronic inflammation
7. OMENTUM #3, PARTIAL OMENECTOMY:

[page 2 of 5]
-Mesothelial-lined lobulated fibroadipose tissue with fibroadhesions, reactive mesothelial hyperplasia and chronic inflammation

8. UTERUS, TOTAL ABDOMINAL HYSTERECTOMY:
- Serosal papillary serous carcinoma
- Atypical leiomyoma (0.9 cm)
- Additional seven leiomyomas (0.5 to 2.2 cm)
- Proliferative endometrium with hyperplastic endometrial polyp
- Chronic cervicitis with squamous metaplasia, endocervical polyp (2.0 cm)
- Bilateral segments of fallopian tube showing surface, serosal vascular congestion and detached poorly preserved atypical epithelial cells, probable tumor cells
9. RIGHT BLADDER PERITONEUM, EXCISION:
- Metastatic papillary serous carcinoma
10. LEFT BLADDER NODULE, EXCISION:
- Metastatic papillary serous carcinoma
- Extensive tumor necrosis and psammomatous calcifications present
11. RECTAL TUMOR, EXCISION:
- Metastatic papillary serous carcinoma
12. RIGHT PERIURETERAL TUMOR, EXCISION:
- Metastatic papillary serous carcinoma
13. APPENDIX, APPENDECTOMY:
- Rare aggregate of malignant tumor cells present on serosal surface
- Acute serositis with vascular congestion
- No parenchyma involvement of the appendix present
- The appendix shows reactive lymphoid hyperplasia

NOTE: Base on the material this tumor is FIGO stage III C T3c NX MX.

=====

HISTORY: Exploratory laparotomy, TAH, BSO with pathology consult, debulking of tumor, staging, omentectomy

MICROSCOPIC:

See Diagnosis.

GROSS:

1: RIGHT TUBE AND OVARY

Labeled "right tube and ovary" and received fresh from the Operating Room for intraoperative frozen section diagnosis and subsequently

(continued on next page)□

fixed in formalin, is a right tube and ovary weighing 370 grams. The entire ovary is replaced by tumor and measures 14.5 x 10.5 x 4.5 cm. Tumor is present on the external surface. However, the capsule is intact. The uninvolved external surface is pink-tan and smooth. Scanty residual recognizable ovary is noted. Cut section reveals tan-white friable, necrotic tumor replacing virtually the entire ovary. The attached fimbriated fallopian tube measures 4.5 cm in length with a diameter that ranges from 0.5 to 0.3 cm. The serosal surface is pink-tan, smooth and focally hemorrhagic. There is a single 0.7 cm thin-walled clear fluid-filled cyst attached to the fallopian tube. No tumor is identified on the fallopian tube. Sectioning the fallopian tube reveals a 0.1 cm patent lumen. Representative sections.

A. Frozen section remnant - 1

B-H. Tumor material - 2 each

[page 3 of 5]
- I. Normal ovary - 2
- J. Normal ovary and fallopian tube - 5

2: LEFT TUBE AND OVARY

Labeled "left tube and ovary" and received in formalin is a left tube and left ovary with attached fallopian tube. The left ovary measures 11.0 x 7.0 x 3.5 cm. The external surface is smooth, soft, tan-pink with focal areas of hemorrhage. Friable grey-white tumor is noted on the external surface. Sectioning the ovary reveals a serosanguinous fluid-filled cyst. The cyst wall varies from 0.1 to 0.2 cm in thickness. The cyst lining is smooth, tan and contains a solid grey-white component measuring 3.5 x 3.0 x 2.0 cm. The attached fimbriated fallopian tube measures 4.0 cm in length and ranges from 0.4 to 0.9 cm in greatest diameter. The external surface of the fallopian tube is smooth, pink-tan, with focal areas of hemorrhage. Sectioning reveals a 0.1 cm patent fallopian tube lumen. No tumor is present on the fallopian tube surface or parenchyma. Representative sections.

- K-M. Tumor - 2 each
- N. Tumor on external surface - 2
- O. Fallopian tube - 2

3: BLADDER BIOPSY

Labeled "bladder biopsy" and received in formalin is a soft red-tan irregular portion of soft tissue measuring 1.5 x 0.5 x 0.5 cm. Entirely submitted.

- P. 1

4: PELVIC TUMOR

Labeled "pelvic tumor" and received in formalin is an aggregate of soft, white-tan irregular friable portions of soft tissue measuring 5.5 x 5.0 x 2.5 cm. Representative sections.

- Q,R. 2 each

5: OMENTUM 1

Labeled "omentum #1" and received in formalin is a soft red-yellow, irregular portion of fibroadipose tissue measuring 14.0 x 13.0 x 2.0 cm. Sectioning reveals firm, white-tan tumor deposits. Representative sections are submitted.

(continued on next page)□

- S. 1

6: OMENTUM 2

Labeled "omentum #2" and received in formalin is a soft red-yellow, irregular portion of fibroadipose tissue measuring 13.5 x 8.5 x 2.0 cm. Sectioning reveals yellow, lobulated adipose tissue with no evidence of tumor deposits. Representative sections.

- T. 2

7: OMENTUM 3

Labeled "omentum #3" and received in formalin is a soft red-tan hemorrhagic irregular portion of fibroadipose tissue measuring 18.5 x 9.0 x 1.5 cm. Sectioning of the tissue reveals lobulated yellow-brown adipose tissue with no evidence of tumor deposits. Representative sections.

- U. 2

8: UTERUS

[page 4 of 5]
Labeled "uterus" and received in formalin is a 140 gram total hysterectomy specimens with portion of bilateral fallopian tubes. The uterus is symmetric. The uterus measures 9.5 cm from the fundus to the ectocervix, 4.0 cm from cornu to cornu and 4.0 cm from anterior surface to posterior surface. The serosal surface is red-tan, smooth and focally bosselated due to subserosal leiomyomas. The cervix is 3.5 cm long and 4.3 cm in diameter in the ectocervical region. The mucosa lining the ectocervix is smooth white-tan and focally hyperemic. The external cervical os is 1.2 cm in diameter and slit-shape. The cervical transformation zone is distinct. The endocervical canal is 2.5 cm long and lined by smooth yellow-tan rugose mucosa. Cut sections of the cervix reveal smooth white-tan cut surfaces with multiple nabothian cysts ranging in size from 0.1 cm to 0.3 cm. The endometrial cavity is 5.0 cm long and up to 3.5 cm wide. Within the posterior endometrial lining is a soft, white-tan 0.6 cm endometrial polyp. The endometrial lining is smooth, white-tan and focally hemorrhagic and ranges from 0.1 to 0.2 cm in thickness. Within the posterior endocervix there is a soft pink-tan irregular shaped polyp measuring 2.0 x 0.4 x 0.4 cm. Within the uterus there are eight well-circumscribed leiomyomas (four subserosal, three intramural, one submucosal) and range from 0.5 cm to 2.2 cm in greatest dimension. Each of the leiomyomas has firm, solid tan-white cut surface of a whorled configuration without grossly evident hemorrhages or areas of necrosis. The uninvolved muscular uterine wall has a maximum thickness of 2.2 cm. The myometrium is smooth, tan. The right fallopian tube is without fimbria and measures 4.5 cm in length and ranges from 0.4 to 0.8 cm in diameter. The external surface of the fallopian tube is smooth, red-tan with focal areas of hemorrhage. Cross sections of the fallopian tube reveal a patent lumen which is less than 0.1 cm in diameter. The left fallopian tube is without fimbria and measures 4.5 cm in length and ranges from 0.2 to 0.7 cm in maximum diameter. The serosal surface is smooth, red-tan and focally hemorrhagic. Cut sections of the left fallopian tube reveal a patent lumen which is less than 0.1 cm in diameter. Representative sections are submitted.

(continued on next page)□

Page: 5

- V. Anterior cervix - 1
- W. Posterior cervix - 1
- X. Endocervical polyp - 1
- Y. Anterior uterine corpus - 1
- Z. Posterior uterine corpus - 1
- AA. Endometrial polyps - 2
- BB. Three subserosal leiomyomas - 3
- CC. One subserosal leiomyoma - 1
- DD. Three intramural leiomyomas - 3
- EE. One submucosal leiomyoma - 1
- FF. Right fallopian tube - 2
- GG. Left fallopian tube - 2

9: RIGHT BLADDER PERITONEAL

Labeled "right bladder peritoneum" and received in formalin is an aggregate of soft red-tan granular, fibromembranous tissue measuring 4.0 x 4.5 x 2.0 cm. There is a soft white-tan irregular mass within the fibromembranous tissue measuring 1.5 x 1.0 x 1.0 cm. Representative sections.

10: LEFT BLADDER NODULE

Labeled "left bladder nodule" and received in formalin is an aggregate of soft red-tan irregular portion of soft tissue measuring 5.0 x 4.0 x 3.0 cm. There are multiple areas of tumor deposits

[page 5 of 5]
ranging in size from 0.7 cm to 1.5 cm in greatest dimension. Representative sections are submitted.

II. 2

11: RECTAL TUMOR

Labeled "rectal tumor" and received in formalin is a soft red-tan irregular portion of tissue measuring 2.0 x 1.8 x 1.0 cm. Representative sections.

12: RIGHT PERI URETERAL TUMOR

Labeled "right periureteral tumor" and received in formalin is an aggregate of soft red-tan irregular portions of soft tissue measuring 4.5 x 3.0 x 2.0 cm. Representative sections.

13: APPENDIX

Labeled "appendix" and received in formalin is an appendix measuring 7.5 cm in length and with a width of 0.7 cm. The periappendiceal fat has a width of 2.5 cm and a thickness of 1.0 cm. The outer surface of the appendix is smooth, red-tan and focally hemorrhagic. The wall thickness ranges from 0.1 cm to 0.3 cm. The lumen contains a moderate amount of soft green, fecal material. There is no fecalith or perforation identified. Representative sections.

(cont: [REDACTED])

[REDACTED] cont.

Page: 6

OPERATIVE CONSULT (FROZEN):

1. Right tube and ovary, FSI:
- Malignant neoplasm, defer permanents for definitive diagnosis
2. Left tube and ovary, gross only:
- Enlarged ovary with solid and cystic areas; solid areas grossly similar to specimen #1

Special Studies: Frozen Section

See Also: [REDACTED]

Source: NCI Genomic Data Commons file 839eba0c-39cf-4a95-a324-a51f69ce0fbc (TCGA-23-1110.07361EFD-0B7D-4DCB-AFE3-464200F59AC0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).